Gene-level copy-number profile of tumor specimen TCGA-P3-A6T4-01A from TCGA case TCGA-P3-A6T4, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 54.8 years (20,027 days).
Specimen TCGA-P3-A6T4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.edc6bbf4-7a10-45a5-88b6-7a7180fc5b0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P3-A6T4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ca3cbadc-10f9-4759-ba3a-5a7ea9b6c987

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 6; copy number 2: 14,615; copy number 3: 18,495; copy number 4: 16,703; copy number 5: 6,998; copy number 6: 1,456; copy number 7: 310; copy number 8: 1,113; copy number 9: 78; copy number 18: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P3-A6T4-01A-11D-A34I-01): tumor purity 0.45, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:34,109,560–34,815,325, 1 gene (within-gene range 0–3): PARD3.
- chr10:34,488,583–34,488,878, 1 gene: ELOBP4.
- chr14:37,171,888–37,187,314, 2 genes: SLC25A21-AS1, RNU6-273P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,543 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:134,437,605–198,222,513, 1,099 genes, copy number 8 (broad region; genes not listed).
- chr11:68,312,591–71,252,577, 68 genes, copy number 9–18 (broad region; genes not listed).
- chr12:22,063,773–22,437,041, 1 gene, copy number 9 (within-gene range 5–9): ST8SIA1.
- chr12:22,195,469–32,646,050, 201 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr22:17,734,138–21,045,017, 174 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
